Somatic mutation profile of tumor specimen C3L-07629-02 (aliquot CPT0484210006) from CPTAC case C3L-07629, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.2 years (22,717 days).
Specimen C3L-07629-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a436621-211c-46ce-9646-94257860e211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07629-31 (Blood Derived Normal), aliquot CPT0484350004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b65d744b-51eb-4e28-9e82-2b669741d01c

The open-access MAF lists 140 somatic variants for this specimen: 104 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 30, Nonsense Mutation 6, Intron 3, Frame Shift Del 3, Splice Site 2, 3'UTR 2, Splice Region 1, RNA 1, In Frame Del 1, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.6127C>A p.Q2043K | Missense Mutation (SNP) | VAF 80/450 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.083); catalogued as COSV52151554; called by muse, mutect2, varscan2
- ASTN1 | c.1358A>C p.N453T | Missense Mutation (SNP) | VAF 74/495 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV56063927; called by muse, mutect2, varscan2
- CDH10 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050671; called by muse, mutect2
- CDK13 | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99475652; called by muse, mutect2, varscan2
- CHODL | c.122A>T p.K41I | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV54735536; called by muse, mutect2
- CLMP | c.1033C>G p.P345A | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1056684540; called by muse, mutect2, varscan2
- COL13A1 | c.769C>T p.R257W (on ENST00000398978 / NM_001130103.2; = p.R200W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs371135447; called by muse, mutect2, varscan2
- EIF3K | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 54/341 reads (16%) | catalogued as rs375893694; called by muse, mutect2, varscan2
- EXPH5 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 17/445 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV56206495; called by muse, mutect2
- FAM186A | c.5752C>T p.R1918* | Nonsense Mutation (SNP) | VAF 34/464 reads (7%) | catalogued as rs1245561935; called by muse, mutect2
- FBXL7 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 95/684 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs1279576968, COSV61644583; called by muse, mutect2, varscan2
- GFRAL | c.194A>C p.Y65S | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61235918; called by muse, mutect2
- GSTT2B | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 32/688 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1223066707; called by muse, mutect2
- H2AC17 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV58152136, COSV58152155; called by muse, mutect2
- H3-4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 40/566 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64211053; called by muse, mutect2
- KCND2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV58575563; called by muse, mutect2, varscan2
- KIR3DL1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs200785070; called by muse, mutect2
- LAMA2 | c.7118C>T p.S2373L | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs758887080, COSV70341720; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LAMA3 | c.2685G>T p.Q895H | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58072940; called by muse, mutect2
- LEFTY2 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 114/622 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100832647; called by muse, mutect2, varscan2
- LGR5 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs763124254, COSV99877729; called by muse, mutect2
- MAPK8IP3 | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 68/404 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490909451, COSV51600989; called by muse, mutect2
- MEGF8 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 93/438 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs376248434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP17 | c.1386C>A p.D462E | Missense Mutation (SNP) | VAF 84/536 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.371); catalogued as rs117508750; called by muse, mutect2, varscan2
- MOV10L1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as rs775255128; called by muse, mutect2, varscan2
- NPHS1 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV62287175; called by muse, mutect2, varscan2
- OR2B3 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 100/736 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs780852474; called by muse, mutect2, varscan2
- OR52E8 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV101190515, COSV66207052, COSV66207977; called by muse, mutect2
- OR56A4 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 94/484 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs756413126; called by muse, mutect2, varscan2
- OR5T1 | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV57302939; called by muse, mutect2, varscan2
- PCDHA7 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100971885; called by muse, mutect2, varscan2
- PCDHGA12 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs773893751; called by muse, mutect2
- PDGFRA | c.1664A>T p.Y555F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM066164, COSV57271583; called by muse, mutect2
- PIK3R5 | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52659382; called by muse, mutect2, varscan2
- PLCH2 | c.123G>A p.L41= | Splice Region (SNP) | VAF 94/379 reads (25%) | catalogued as rs1241969278, COSV53941792; called by muse, mutect2, varscan2
- PREX2 | c.2138T>G p.L713R | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771704; called by muse, mutect2, varscan2
- PRKN | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58237317, COSV58292613; called by muse, mutect2, varscan2
- PRSS51 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 39/506 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1031781387; called by muse, mutect2
- RFPL2 | c.857G>T p.R286L | Missense Mutation (SNP) | VAF 42/582 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs748164882; called by muse, mutect2
- RP1 | c.4664G>T p.G1555V | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV99607088, COSV99608479; called by muse, mutect2, varscan2
- SCAMP1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs750834214; called by muse, mutect2, varscan2
- SDK1 | c.2974T>A p.W992R | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67381120; called by muse, mutect2
- SLF2 | c.3328C>T p.R1110W | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs186024334; called by muse, mutect2, varscan2
- SMAD2 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51013316; called by muse, mutect2, varscan2
- SUSD2 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200686756; called by muse, mutect2
- SVOPL | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 49/285 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1267447364; called by muse, mutect2, varscan2
- TAS2R4 | c.548T>G p.L183W | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56093174; called by muse, mutect2, varscan2
- TBX3 | c.807del p.T270Hfs*12 (on ENST00000257566 / NM_016569.4; = p.T250Hfs*12 on NM_005996.4) | Frame Shift Del (DEL) | VAF 40/394 reads (10%) | catalogued as COSV57474269; called by mutect2, pindel, varscan2
- TP53 | c.286del p.S96Lfs*27 | Frame Shift Del (DEL) | VAF 159/593 reads (27%) | catalogued as COSV52760633; called by mutect2, pindel, varscan2
- TUBA3C | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.4); catalogued as rs746849086, COSV68027412, COSV68027928; called by muse, mutect2
- ZFHX3 | c.4826C>T p.S1609F | Missense Mutation (SNP) | VAF 77/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs928080463; called by muse, mutect2, varscan2
- ZNF618 | c.2219C>T p.T740M (on ENST00000374126 / NM_001318042.2; = p.T647M on NM_133374.2) | Missense Mutation (SNP) | VAF 62/455 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs375702223; called by muse, mutect2, varscan2
- ZNF749 | c.1988C>A p.T663N | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs774592911; called by muse, mutect2, varscan2
- ZNF821 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV100546872; called by muse, mutect2
- AGBL1 | c.2206T>C p.Y736H | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ANKRD29 | c.729dup p.T244Dfs*14 | Frame Shift Ins (INS) | VAF 26/242 reads (11%) | called by mutect2, pindel
- ASB18 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 78/539 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BCAS3 | c.2395C>T p.P799S (on ENST00000390652 / NM_001353144.2; = p.P784S on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BCL9L | c.909_923del p.L306_P310del | In Frame Del (DEL) | VAF 84/542 reads (15%) | called by mutect2, pindel, varscan2
- CATSPER4 | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 101/415 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- CDH9 | c.1318A>T p.I440F | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- COL3A1 | c.2252C>A p.A751D | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CSNK1G3 | c.1304T>A p.F435Y | Missense Mutation (SNP) | VAF 21/307 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2
- CYP4A11 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DCHS1 | c.6712G>T p.E2238* | Nonsense Mutation (SNP) | VAF 39/309 reads (13%) | called by muse, mutect2, varscan2
- DLGAP4 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 56/547 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DSC1 | c.2529T>A p.C843* | Nonsense Mutation (SNP) | VAF 17/363 reads (5%) | called by muse, mutect2
- DSCAML1 | c.3727T>C p.Y1243H (on ENST00000321322; = p.Y1183H on NM_020693.4) | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ELOA2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 24/535 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESR1 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FAT3 | c.5249C>T p.A1750V | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FCRL6 | c.809A>T p.D270V | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- HHIPL1 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- KCNA4 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 34/575 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KNTC1 | c.516T>G p.I172M | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LAMA1 | c.7367del p.G2456Afs*22 | Frame Shift Del (DEL) | VAF 39/287 reads (14%) | called by mutect2, pindel, varscan2
- LRRC9 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MAF | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MC5R | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 65/363 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MOGS | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 100/536 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MPP4 | c.125T>A p.F42Y | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTRF1 | c.1336T>G p.*446Eext*8 | Nonstop Mutation (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- NEB | c.12828T>G p.F4276L | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NEB | c.12827T>A p.F4276Y | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- NUP153 | c.2850T>A p.F950L | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- OR8B4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/190 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by mutect2, varscan2
- PXDNL | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 30/644 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.103); called by muse, mutect2
- RIPOR2 | c.1920+1G>C p.X640_splice | Splice Site (SNP) | VAF 16/152 reads (11%) | called by muse, varscan2
- SFTPD | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 72/457 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRTN | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 21/517 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2
- SRSF12 | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- SUMF2 | c.372A>T p.R124S (on ENST00000652303; = p.R105S on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.175); called by muse, mutect2
- TAS1R1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 103/494 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TEX30 | c.15+1G>A p.X5_splice | Splice Site (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- TMBIM4 | c.539T>A p.L180* | Nonsense Mutation (SNP) | VAF 14/323 reads (4%) | called by muse, mutect2
- TOP2A | c.2149T>C p.S717P | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRPC5 | c.1790C>G p.T597S | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UAP1L1 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VARS2 | c.2138G>A p.C713Y | Missense Mutation (SNP) | VAF 90/550 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- WDR45B | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- XPO6 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ZNF521 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 45/390 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ZNF865 | c.349T>C p.S117P | Missense Mutation (SNP) | VAF 42/654 reads (6%) | SIFT tolerated, low confidence (0.32); called by muse, mutect2
- ZNF91 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- B3GALT4 | c.681G>A p.L227= | Silent (SNP) | VAF 50/960 reads (5%) | called by muse, mutect2
- CACNA2D4 | c.2832G>A p.S944= | Silent (SNP) | VAF 214/475 reads (45%) | catalogued as rs375441882; called by muse, mutect2, varscan2
- CD36 | c.285T>A p.V95= | Silent (SNP) | VAF 43/238 reads (18%) | called by muse, mutect2, varscan2
- CGNL1 | c.2289G>C p.L763= | Silent (SNP) | VAF 35/299 reads (12%) | called by muse, mutect2, varscan2
- CHST4 | c.600C>T p.I200= | Silent (SNP) | VAF 79/557 reads (14%) | catalogued as rs752000094, COSV58296411; called by muse, mutect2, varscan2
- CHTF18 | c.636C>T p.G212= | Silent (SNP) | VAF 64/424 reads (15%) | catalogued as rs767596492, COSV50100143; called by muse, mutect2, varscan2
- DDX46 | c.783C>T p.V261= | Silent (SNP) | VAF 35/226 reads (15%) | called by muse, mutect2, varscan2
- DYSF | c.3021C>T p.V1007= | Silent (SNP) | VAF 44/272 reads (16%) | catalogued as rs776969552, COSV99243272; called by muse, varscan2
- GPR87 | c.435G>A p.K145= | Silent (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- GRIK3 | c.1659C>T p.S553= | Silent (SNP) | VAF 80/398 reads (20%) | catalogued as rs752777974, COSV66140685; called by muse, mutect2, varscan2
- GSTA1 | c.102T>C p.F34= | Silent (SNP) | VAF 18/108 reads (17%) | called by mutect2, varscan2
- IL7R | c.1335A>G p.Q445= | Silent (SNP) | VAF 23/464 reads (5%) | called by muse, mutect2
- KCNQ4 | c.1773C>T p.P591= | Silent (SNP) | VAF 73/329 reads (22%) | catalogued as COSV100714361, COSV61275436; called by muse, mutect2, varscan2
- KIF2B | c.693G>A p.K231= | Silent (SNP) | VAF 36/525 reads (7%) | called by muse, mutect2
- LRRC8B | c.2411G>A p.*804= | Silent (SNP) | VAF 19/243 reads (8%) | catalogued as COSV100446714; called by muse, mutect2
- MAST4 | c.4698G>T p.L1566= (on ENST00000403625 / NM_001164664.2; = p.L1377= on NM_015183.3) | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- NAT8L | c.132C>A p.A44= | Silent (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- NAV1 | c.3078C>T p.S1026= | Silent (SNP) | VAF 80/496 reads (16%) | catalogued as rs776167179; called by muse, varscan2
- NOTCH3 | c.6024G>C p.P2008= | Silent (SNP) | VAF 34/508 reads (7%) | catalogued as COSV54630340; called by muse, mutect2
- OR4M1 | c.751C>T p.L251= | Silent (SNP) | VAF 38/730 reads (5%) | called by muse, mutect2
- OR56A5 | c.507C>G p.L169= | Silent (SNP) | VAF 19/424 reads (4%) | called by muse, mutect2
- OR6K2 | c.459C>T p.I153= | Silent (SNP) | VAF 20/540 reads (4%) | called by muse, mutect2
- PDZRN3 | c.1929C>T p.C643= | Silent (SNP) | VAF 39/358 reads (11%) | catalogued as rs368693865, COSV55205808; called by muse, varscan2
- PLCB2 | c.1074A>G p.L358= | Silent (SNP) | VAF 36/444 reads (8%) | catalogued as rs1467263816; called by muse, mutect2
- RIMS1 | c.306G>A p.A102= | Silent (SNP) | VAF 51/315 reads (16%) | catalogued as rs749369997, COSV53436463; called by muse, mutect2, varscan2
- RP1 | c.4665A>T p.G1555= | Silent (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- SPATA17 | c.492G>A p.K164= | Silent (SNP) | VAF 51/316 reads (16%) | called by muse, mutect2, varscan2
- TENM2 | c.1215A>G p.Q405= | Silent (SNP) | VAF 80/311 reads (26%) | called by muse, mutect2, varscan2
- TENM4 | c.3675C>T p.D1225= | Silent (SNP) | VAF 90/426 reads (21%) | catalogued as rs569641503; called by muse, mutect2, varscan2
- ZFAT | c.2568C>T p.V856= | Silent (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- AHI1 | c.135+419G>T | Intron (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- CHTF8 | c.141+75G>C | Intron (SNP) | VAF 68/452 reads (15%) | called by muse, mutect2, varscan2
- CPLX4 | c.*1G>T | 3'UTR (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- DCHS2 | n.7598A>G | RNA (SNP) | VAF 67/395 reads (17%) | catalogued as rs550433116; called by muse, mutect2, varscan2
- DNAH14 | c.2938+1860G>T | Intron (SNP) | VAF 39/444 reads (9%) | called by muse, mutect2
- PSG3 | c.*125C>T | 3'UTR (SNP) | VAF 44/335 reads (13%) | catalogued as rs1359302660; called by muse, mutect2, varscan2
